Somatic mutation profile of tumor specimen 0DG38A from CCDI case PBBSUK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 6.3 years (2,303 days).
Specimen 0DG38A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85e981e3-edf4-468f-b07f-71481f4fa327.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG388 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/274f708a-1b45-4668-acf0-427d409a1d8e

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, 3'UTR 2, Intron 1, Splice Site 1, RNA 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 410/914 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- CCDC7 | c.796+1G>A p.X266_splice | Splice Site (SNP) | VAF 445/834 reads (53%) | catalogued as rs150437631; called by muse, mutect2, varscan2
- DDX3X | c.821C>G p.T274R (on ENST00000399959; = p.T275R on NM_001356.5) | Missense Mutation (SNP) | VAF 384/1005 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67863061; called by muse, mutect2, varscan2
- JUP | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 281/948 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs397517298, COSV100159478; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTUS2 | c.2381C>T p.A794V | Missense Mutation (SNP) | VAF 120/545 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs751719260, COSV101462339, COSV70916698; called by muse, mutect2, varscan2
- POLR1B | c.2512G>A p.V838M | Missense Mutation (SNP) | VAF 63/662 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); catalogued as rs1298140755; called by muse, mutect2, varscan2
- RASAL2 | c.3037C>T p.R1013C | Missense Mutation (SNP) | VAF 182/924 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1363136360; called by muse, mutect2, varscan2
- TENM1 | c.5313G>A p.W1771* | Nonsense Mutation (SNP) | VAF 191/1121 reads (17%) | catalogued as COSV64442033; called by muse, mutect2, varscan2
- TRAPPC1 | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 69/270 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs762780173; called by muse, mutect2, varscan2
- CBARP | c.374G>A p.R125Q (on ENST00000382477; = p.R131Q on NM_152769.3) | Missense Mutation (SNP) | VAF 79/631 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TADA1 | c.495C>A p.D165E | Missense Mutation (SNP) | VAF 451/827 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- NHS | c.1263C>T p.S421= | Silent (SNP) | VAF 130/1284 reads (10%) | catalogued as rs775867910; called by muse, varscan2
- CR2 | c.1979-105G>C | Intron (SNP) | VAF 432/788 reads (55%) | called by muse, mutect2, varscan2
- DCXR | c.*11C>A | 3'UTR (SNP) | VAF 30/392 reads (8%) | called by muse, mutect2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 17/347 reads (5%) | called by muse, mutect2
- TMEM250 | c.*28G>A | 3'UTR (SNP) | VAF 52/143 reads (36%) | catalogued as rs1240403414; called by muse, mutect2, varscan2
